Somatic mutation profile of tumor specimen 0DMBMC from CCDI case PBCAIZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.3 years (3,747 days).
Specimen 0DMBMC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7f48652-a91f-4e70-9316-c5ce19e0448a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMBLK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1df5ecc0-a131-4d7d-8c6d-e16f6c5d64b9

The open-access MAF lists 24 somatic variants for this specimen: 14 protein-altering or splice-affecting, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 4, 3'UTR 3, RNA 2, Splice Region 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNGB1 | c.1798C>T p.P600S | Missense Mutation (SNP) | VAF 284/754 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.441); catalogued as rs1410742659; called by muse, mutect2
- FUBP1 | c.1926+6A>G | Splice Region (SNP) | VAF 32/731 reads (4%) | catalogued as rs1274056962; called by muse, mutect2
- MUC16 | c.12618G>A p.M4206I | Missense Mutation (SNP) | VAF 225/641 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV67459273; called by muse, mutect2, varscan2
- MUC4 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 57/1002 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.685); catalogued as rs781336737, COSV62154434; called by muse, mutect2
- PARD3 | c.1046G>T p.R349L | Missense Mutation (SNP) | VAF 183/616 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs199923448, COSV60745933; called by muse, mutect2, varscan2
- PRKD1 | c.2305G>A p.V769I | Missense Mutation (SNP) | VAF 106/526 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV59558857; called by muse, mutect2, varscan2
- CADPS2 | c.3397G>T p.V1133L | Missense Mutation (SNP) | VAF 313/628 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- DMXL2 | c.5905G>T p.V1969F | Missense Mutation (SNP) | VAF 193/996 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERICH6 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 52/712 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.051); called by muse, mutect2
- HSP90AB1 | c.1247_1249del p.F416del | In Frame Del (DEL) | VAF 266/784 reads (34%) | called by pindel, varscan2
- LEP | c.429G>T p.E143D | Missense Mutation (SNP) | VAF 60/1038 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- OPA1 | c.1326A>T p.K442N (on ENST00000361510 / NM_130837.3; = p.K387N on NM_015560.3) | Missense Mutation (SNP) | VAF 157/511 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PRAMEF11 | c.125T>A p.F42Y | Missense Mutation (SNP) | VAF 50/786 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- VCAM1 | c.1782A>T p.L594F | Missense Mutation (SNP) | VAF 28/1067 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANGPT2 | c.*46C>G | 3'UTR (SNP) | VAF 16/430 reads (4%) | called by muse, mutect2
- ANKRD30BP2 | n.1071A>T | RNA (SNP) | VAF 233/601 reads (39%) | called by muse, varscan2
- AP4E1 | c.*1656G>A | 3'UTR (SNP) | VAF 8/206 reads (4%) | called by muse, mutect2
- ATP7B | c.3556+68G>C | Intron (SNP) | VAF 14/382 reads (4%) | called by muse, mutect2
- CCNJP1 | n.326C>T | RNA (SNP) | VAF 213/558 reads (38%) | called by muse, mutect2, varscan2
- IFT43 | c.54+46G>A | Intron (SNP) | VAF 18/362 reads (5%) | called by muse, mutect2
- LANCL2 | c.*4G>A | 3'UTR (SNP) | VAF 70/908 reads (8%) | catalogued as rs1166192384; called by muse, mutect2
- LST1 | c.112+94G>A | Intron (SNP) | VAF 92/253 reads (36%) | called by muse, mutect2, varscan2
- STMN3 | c.-70C>G | 5'UTR (SNP) | VAF 41/281 reads (15%) | called by muse, mutect2, varscan2
- TMEM63A | c.1086-27C>G | Intron (SNP) | VAF 211/1090 reads (19%) | called by muse, mutect2, varscan2
